Somatic mutation profile of tumor specimen TCGA-13-1405-01A (aliquot TCGA-13-1405-01A-01W-0494-09) from TCGA case TCGA-13-1405, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.9 years (18,218 days).
Specimen TCGA-13-1405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d10e338-90b5-4447-b6a0-4107a39796d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1405-10A (Blood Derived Normal), aliquot TCGA-13-1405-10A-01W-0495-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4517a66b-4723-4339-878b-8b859fb70db0

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, Intron 1, Splice Site 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 52/117 reads (44%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs766202428, COSV57924399; called by muse, mutect2, varscan2
- ACP6 | c.709_710insT p.D237Vfs*6 | Frame Shift Ins (INS) | VAF 34/154 reads (22%) | catalogued as COSV65076363; called by pindel, varscan2
- AGAP4 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV71164803; called by muse, mutect2, varscan2
- AGL | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV54049048; called by muse, mutect2, varscan2
- C2CD2 | c.2013G>T p.R671S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100298000; called by muse, mutect2
- CAPRIN1 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58218799, COSV58221612; called by muse, mutect2, varscan2
- CENPE | c.7416G>A p.M2472I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54377552; called by muse, mutect2, varscan2
- COCH | c.1042G>A p.E348K (on ENST00000216361 / NM_001347720.1; = p.E283K on NM_004086.3) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs1224796113, COSV53551713; called by muse, mutect2
- COL4A6 | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV57860839; called by muse, mutect2, varscan2
- DDX56 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99215499; called by muse, mutect2
- DOLK | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100454955; called by muse, mutect2, varscan2
- EML2 | c.1694-1G>A p.X565_splice | Splice Site (SNP) | VAF 37/109 reads (34%) | catalogued as rs751787095, COSV55598057; called by muse, mutect2, varscan2
- EPHA3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 111/398 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750948534, COSV60697531; called by muse, mutect2, varscan2
- FSCB | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV61217034; called by muse, mutect2, varscan2
- GBP1 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 92/281 reads (33%) | catalogued as COSV65082861; called by muse, mutect2, varscan2
- GPR75 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61825501; called by muse, mutect2, varscan2
- GRIN3A | c.2285C>A p.A762E | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62451231; called by muse, mutect2
- HMCN1 | c.13660C>G p.R4554G | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54879272, COSV99624320; called by muse, mutect2
- KIF16B | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 21/614 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100733786; called by muse, mutect2
- MXRA5 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 7/119 reads (6%) | catalogued as COSV99475799; called by muse, mutect2
- MYO1D | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59008895; called by muse, mutect2, varscan2
- NIN | c.4675G>A p.E1559K (on ENST00000382041 / NM_182946.1; = p.E846K on NM_016350.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV55382919; called by muse, mutect2, varscan2
- OLFM3 | c.1403T>G p.L468R (on ENST00000338858 / NM_001288821.1; = p.L448R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58796472, COSV58798470; called by muse, mutect2
- OLFML1 | c.757C>G p.P253A | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV55075089; called by muse, mutect2, varscan2
- OR2C1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs745587784, COSV100514853; called by muse, mutect2, varscan2
- OR6N1 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV58647599; called by muse, mutect2, varscan2
- OR8H3 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 160/422 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57907776; called by mutect2, varscan2
- PAX9 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs974072582, COSV64061296, COSV64062025; called by muse, mutect2, varscan2
- PPM1H | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV99955208; called by muse, mutect2
- PREX2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99905136; called by muse, mutect2
- RALGAPA2 | c.4651G>A p.G1551S | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs1240401723, COSV99173151; called by muse, mutect2
- RBKS | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as COSV100141949; called by muse, mutect2
- RIF1 | c.2489T>A p.I830N | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99690076; called by muse, mutect2
- SCFD2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV66369641; called by muse, mutect2, varscan2
- SF3B3 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56785892; called by muse, mutect2, varscan2
- SLITRK1 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV65674069; called by muse, mutect2, varscan2
- TNXB | c.7099G>T p.G2367C (on ENST00000647633; = p.G2120C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV64475068, COSV64482457; called by muse, mutect2
- UHMK1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.69); catalogued as COSV99966128; called by muse, mutect2, varscan2
- WFDC5 | c.98dup p.C34Lfs*5 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | catalogued as rs767342014; called by pindel, varscan2
- ZBTB21 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV100176918; called by muse, mutect2, varscan2
- ZBTB21 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100176922; called by muse, mutect2, varscan2
- DNAJB5 | c.509dup p.V171Sfs*30 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, pindel
- NAA15 | c.1963del p.E655Kfs*7 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- TTN | c.60063del p.E20021Dfs*34 (on ENST00000591111; = p.E12597Dfs*34 on NM_003319.4) | Frame Shift Del (DEL) | VAF 59/447 reads (13%) | called by mutect2, pindel
- CCDC191 | c.1050G>T p.L350= | Silent (SNP) | VAF 353/1498 reads (24%) | catalogued as COSV55670716; called by muse, mutect2, varscan2
- DEPDC5 | c.2937G>A p.Q979= (on ENST00000400246; = p.Q1048= on NM_014662.5) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1360554872, COSV56692780; called by muse, mutect2, varscan2
- DNAH9 | c.7065C>A p.L2355= | Silent (SNP) | VAF 9/200 reads (5%) | catalogued as COSV99304186; called by muse, mutect2
- GIMAP8 | c.1359G>A p.A453= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs376371559; called by muse, mutect2, varscan2
- IRGQ | c.324C>T p.T108= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1168648575, COSV60670301; called by muse, mutect2, varscan2
- SIGLEC11 | c.1290C>T p.H430= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs201076601, COSV70221904; called by muse, mutect2, varscan2
- SLC39A7 | c.477G>A p.E159= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as rs756514650, COSV100807590; called by muse, mutect2
- SYNE2 | c.2460A>G p.K820= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV59942397; called by muse, mutect2, varscan2
- TUT4 | c.2058C>T p.S686= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV57110990; called by mutect2, varscan2
- CEP295 | c.5851-127C>G | Intron (SNP) | VAF 86/294 reads (29%) | catalogued as COSV57346532; called by muse, varscan2
- MIR520D | n.79G>A | RNA (SNP) | VAF 178/770 reads (23%) | catalogued as rs748269980; called by muse, mutect2, varscan2
